Somatic mutation profile of tumor specimen ALCH-B2BN-TTP1-A (aliquot ALCH-B2BN-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2BN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.1 years (20,112 days).
Specimen ALCH-B2BN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e59d59bc-90ce-4ef0-9d52-a5f372cd7349.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2BN-NB1-A (Blood Derived Normal), aliquot ALCH-B2BN-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1ea6194-6b1e-4650-8c20-db6b58d6a4fc

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 4, Splice Site 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG2 | c.256-1G>T p.X86_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as rs1558625926; called by muse, mutect2
- DDX42 | c.839A>T p.Q280L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336331695; called by muse, mutect2, varscan2
- HTR1A | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV60502277; called by muse, mutect2
- KIF1C | c.1968del p.E657Kfs*91 | Frame Shift Del (DEL) | VAF 20/180 reads (11%) | catalogued as COSV57902816; called by mutect2, pindel, varscan2
- NWD2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 11/361 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs867133582, COSV58748114; called by muse, mutect2
- SLITRK4 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62023555; called by muse, mutect2, varscan2
- SSX5 | c.304G>A p.G102S (on ENST00000347757 / NM_175723.1; = p.G143S on NM_021015.4) | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs782674274, COSV100308743; called by muse, mutect2, varscan2
- TENM3 | c.7468G>A p.A2490T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1204311486, COSV69314988; called by muse, mutect2, varscan2
- ZNF48 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs771845027; called by muse, mutect2, varscan2
- APOL4 | c.54A>C p.Q18H (on ENST00000352371 / NM_145660.2; = p.Q15H on NM_030643.4) | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2
- CARNMT1 | c.700dup p.M234Nfs*14 | Frame Shift Ins (INS) | VAF 24/133 reads (18%) | called by mutect2, pindel, varscan2
- CHADL | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, varscan2
- FMN2 | c.4169A>C p.D1390A | Missense Mutation (SNP) | VAF 66/353 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMR1 | c.1069G>C p.D357H | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.245); called by muse, mutect2
- KRTAP10-1 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LRRC34 | c.162G>C p.Q54H | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NHS | c.4318T>A p.S1440T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- NPY5R | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIMREG | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLXNA3 | c.4680C>G p.N1560K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RBM39 | c.132T>A p.S44R | Missense Mutation (SNP) | VAF 61/493 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TMEM121B | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- UBQLNL | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2
- CSMD1 | c.5352C>T p.S1784= (on ENST00000520002; = p.S1783= on NM_033225.6) | Silent (SNP) | VAF 57/379 reads (15%) | catalogued as rs539146933, COSV59324419; called by muse, mutect2
- HUWE1 | c.5985G>A p.T1995= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as rs782666411, COSV53343563; called by muse, mutect2
- INSL6 | c.321T>C p.S107= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs751885775; called by muse, mutect2, varscan2
- MS4A12 | c.138T>G p.A46= | Silent (SNP) | VAF 36/388 reads (9%) | called by muse, mutect2
- MIR329-1 | n.47C>T | RNA (SNP) | VAF 14/83 reads (17%) | catalogued as rs752539396; called by muse, mutect2, varscan2
